Somatic mutation profile of tumor specimen TCGA-BR-7717-01A (aliquot TCGA-BR-7717-01A-11D-2053-08) from TCGA case TCGA-BR-7717, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 63.2 years (23,102 days).
Specimen TCGA-BR-7717-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44bfe7ee-c5a7-4f7f-b464-d90e41c59a1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-7717-10A (Blood Derived Normal), aliquot TCGA-BR-7717-10A-01D-2053-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90b961c2-54a7-4ac8-9332-fe8086478be5

The open-access MAF lists 143 somatic variants for this specimen: 100 protein-altering or splice-affecting, 40 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 40, Nonsense Mutation 3, In Frame Del 2, 5'Flank 1, Intron 1, Splice Region 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AARS2 | c.2866G>A p.G956S | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55114852; called by muse, mutect2, varscan2
- ABCC2 | c.2148G>T p.K716N | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1416560742, COSV64986381, COSV64988246; called by muse, mutect2, varscan2
- ADGRL2 | c.1424A>T p.K475M | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as COSV54668238; called by muse, mutect2, varscan2
- AKAP13 | c.5128C>T p.H1710Y (on ENST00000394518 / NM_007200.5; = p.H1714Y on NM_006738.6) | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.879); catalogued as COSV63457916; called by muse, mutect2, varscan2
- ANKRD28 | c.1604A>T p.E535V | Missense Mutation (SNP) | VAF 48/81 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV67518163; called by muse, mutect2, varscan2
- AP2A2 | c.1351A>G p.I451V | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as rs1186314591, COSV59960481; called by muse, mutect2, varscan2
- AP3M2 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 84/299 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1313487729, COSV51527429; called by muse, mutect2, varscan2
- ASAP1 | c.2950C>G p.P984A | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); catalogued as COSV63048773; called by muse, mutect2, varscan2
- ASH1L | c.3149G>A p.R1050K | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.159); catalogued as COSV64208247; called by muse, mutect2, varscan2
- ATM | c.8369G>A p.R2790K | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); catalogued as COSV53745581; called by muse, mutect2, varscan2
- BBS9 | c.1626A>T p.K542N (on ENST00000242067 / NM_001348036.1; = p.K502N on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54168987; called by muse, mutect2, varscan2
- BMI1 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV100936326, COSV64958761; called by muse, mutect2, varscan2
- CCDC42 | c.163C>A p.H55N | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV53448804; called by muse, mutect2, varscan2
- CCNA1 | c.909A>G p.I303M | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV55221708; called by muse, mutect2, varscan2
- CDH11 | c.1900G>T p.V634L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV99218513; called by muse, mutect2, varscan2
- CNDP2 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as COSV60840036; called by muse, mutect2, varscan2
- CNTNAP4 | c.2458T>C p.F820L | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV56681724; called by muse, mutect2, varscan2
- CPAMD8 | c.1858G>A p.D620N (on ENST00000651564; = p.D573N on NM_015692.5) | Missense Mutation (SNP) | VAF 64/106 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1042762533, COSV52233487; called by muse, mutect2, varscan2
- CPXCR1 | c.623T>A p.L208H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV52162408; called by muse, mutect2, varscan2
- DDX19B | c.323A>G p.Y108C | Missense Mutation (SNP) | VAF 5/126 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as rs1158447296, COSV55363954; called by muse, mutect2
- DEPDC1 | c.854A>T p.D285V | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV63958341; called by muse, mutect2, varscan2
- DNAH5 | c.9425A>C p.K3142T | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54226849; called by muse, mutect2, varscan2
- DOCK4 | c.2056G>A p.V686M | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as rs753651816, COSV70237204; called by muse, mutect2, varscan2
- DUOX1 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.034); catalogued as rs147597074; called by muse, mutect2, varscan2
- DYSF | c.2776T>C p.W926R | Missense Mutation (SNP) | VAF 161/662 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50357947; called by muse, mutect2, varscan2
- EFTUD2 | c.2815C>T p.R939C | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1248922713, COSV53655649; called by muse, mutect2, varscan2
- EIF2B2 | c.780C>G p.H260Q | Missense Mutation (SNP) | VAF 97/393 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1334530547, COSV56720469; called by muse, mutect2, varscan2
- EXOC1 | c.2225G>A p.R742Q | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs373611067, COSV100637863; called by muse, mutect2, varscan2
- FKBP15 | c.1018C>G p.L340V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.95); PolyPhen benign (0.038); catalogued as COSV53035108; called by muse, mutect2, varscan2
- FMN1 | c.2589T>G p.N863K (on ENST00000616417 / NM_001277313.2; = p.N640K on NM_001103184.4) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV57923438; called by muse, mutect2, varscan2
- FOXG1 | c.688C>G p.R230G | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57396963; called by muse, mutect2, varscan2
- GABRP | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as rs781550114, COSV54662402; called by muse, mutect2, varscan2
- GHRL | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 82/306 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as COSV55055630; called by muse, mutect2, varscan2
- GLDC | c.539A>G p.Q180R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58680340; called by muse, mutect2, varscan2
- GNRHR | c.388T>C p.F130L | Missense Mutation (SNP) | VAF 79/102 reads (77%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV56933625; called by muse, mutect2, varscan2
- GP5 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as rs771718752, COSV55464794; called by muse, mutect2, varscan2
- GPR101 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV53238740; called by muse, mutect2, varscan2
- GPR157 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765736117, COSV66233647; called by muse, mutect2, varscan2
- GRIN3A | c.835T>G p.F279V | Missense Mutation (SNP) | VAF 14/185 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.297); catalogued as rs1254592748, COSV62454102; called by muse, mutect2
- HMCN1 | c.11188A>C p.T3730P | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV54902300; called by muse, mutect2, varscan2
- ITCH | c.2203G>A p.E735K (on ENST00000262650 / NM_001257137.3; = p.E694K on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as COSV52932203; called by muse, mutect2, varscan2
- KDM6A | c.1646G>C p.R549T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.643); catalogued as COSV65040438, COSV65045757; called by muse, mutect2
- KRTAP9-3 | c.216G>C p.Q72H | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0.03); catalogued as COSV101370160; called by muse, mutect2, varscan2
- LAMA2 | c.3367A>T p.K1123* | Nonsense Mutation (SNP) | VAF 12/117 reads (10%) | catalogued as COSV70347760; called by muse, mutect2, varscan2
- LAMC2 | c.2714_2716del p.E905del | In Frame Del (DEL) | VAF 17/63 reads (27%) | catalogued as rs1179496469; called by pindel, varscan2
- LYST | c.163C>G p.L55V | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1182404827, COSV67707240; called by muse, mutect2, varscan2
- MAB21L1 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59786473; called by muse, mutect2, varscan2
- MAP2 | c.3215T>G p.L1072R | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.305); catalogued as rs576483648, COSV52291878; called by muse, mutect2, varscan2
- MAP2K3 | c.136T>C p.S46P (on ENST00000342679 / NM_145109.3; = p.S17P on NM_002756.4) | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV57567812; called by muse, mutect2
- MARK3 | c.540G>A p.K180= | Splice Region (SNP) | VAF 14/67 reads (21%) | catalogued as rs1424796733, COSV53510556; called by muse, mutect2, varscan2
- MINAR1 | c.29T>A p.F10Y | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.335); catalogued as COSV59583206; called by muse, mutect2, varscan2
- MSL3 | c.1196C>T p.S399F (on ENST00000312196 / NM_078629.4; = p.S233F on NM_006800.4) | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56493371; called by muse, mutect2, varscan2
- MYCBP2 | c.11918C>G p.A3973G (on ENST00000357337; = p.A4011G on NM_015057.5) | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100629800, COSV62020317; called by muse, mutect2, varscan2
- MYH1 | c.3454G>A p.E1152K | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs759467878, COSV56848963; called by muse, mutect2, varscan2
- MYH6 | c.4613A>G p.E1538G | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV62450783; called by muse, mutect2, varscan2
- NUP188 | c.2327C>G p.T776R | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV65362392; called by muse, mutect2, varscan2
- NWD1 | c.1994G>A p.R665H | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs772407281, COSV60342990; called by muse, mutect2, varscan2
- OR5V1 | c.178T>C p.Y60H | Missense Mutation (SNP) | VAF 43/208 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65828089; called by muse, mutect2, varscan2
- OR8D1 | c.106G>T p.V36L | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV63442324, COSV63443269; called by muse, mutect2
- OTOF | c.3239G>A p.R1080H (on ENST00000272371 / NM_194248.3; = p.R333H on NM_004802.4) | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs397515598, CM094709, COSV55503487; called by muse, mutect2, varscan2
- PDE9A | c.870C>G p.I290M | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.075); catalogued as COSV52326276; called by muse, mutect2, varscan2
- PEG3 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.725); catalogued as rs138383423; called by muse, mutect2, varscan2
- PJA1 | c.745A>T p.K249* | Nonsense Mutation (SNP) | VAF 20/38 reads (53%) | catalogued as COSV100824727; called by muse, mutect2, varscan2
- PRDM9 | c.279A>C p.E93D | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.935); catalogued as COSV57006794, COSV57014064; called by muse, varscan2
- PRM1 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 33/104 reads (32%) | PolyPhen benign (0.081); catalogued as rs752457770, COSV54112837, COSV54113237; called by muse, mutect2, varscan2
- PRX | c.3422C>T p.A1141V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as rs201233076, COSV52521261; called by muse, mutect2, varscan2
- RASSF8 | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 45/151 reads (30%) | catalogued as rs746592311, COSV51453640; called by muse, mutect2, varscan2
- RICTOR | c.3329G>A p.R1110H | Missense Mutation (SNP) | VAF 13/178 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs766067681, COSV57122360, COSV99705554; called by muse, mutect2
- RRBP1 | c.3511C>T p.R1171W (on ENST00000377813 / NM_001365613.2; = p.R738W on NM_004587.3) | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs1374708828, COSV55698663; called by muse, mutect2, varscan2
- RTF2 | c.470G>A p.C157Y | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50128684; called by muse, mutect2, varscan2
- SDK1 | c.5489G>A p.G1830D | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745305864, COSV67369654; called by muse, mutect2, varscan2
- SEMA4C | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59691194; called by muse, mutect2, varscan2
- SESTD1 | c.130A>C p.S44R | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV70567730; called by muse, mutect2
- SF1 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57111668; called by muse, mutect2, varscan2
- SGCZ | c.694T>G p.F232V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV101172137, COSV66016847; called by muse, mutect2, varscan2
- SIL1 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV54531711; called by muse, mutect2, varscan2
- SMC4 | c.1802A>G p.D601G | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as COSV61004949; called by muse, mutect2, varscan2
- STARD8 | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52926741; called by muse, mutect2, varscan2
- STOML3 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.313); catalogued as rs753468566, COSV65510775; called by muse, mutect2, varscan2
- SYNCRIP | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV62287772; called by muse, mutect2, varscan2
- TAF4B | c.1196T>G p.L399R | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.347); catalogued as COSV52302043; called by muse, mutect2
- TAFA4 | c.259A>C p.T87P | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55138129; called by muse, mutect2, varscan2
- TANGO6 | c.276G>T p.W92C | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55765826; called by muse, mutect2, varscan2
- TBKBP1 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs764036278, COSV64653674; called by muse, mutect2, varscan2
- TECTA | c.5669G>A p.R1890H | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs371520052; called by muse, mutect2, varscan2
- TENM4 | c.2741A>C p.N914T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.202); catalogued as COSV53630664; called by muse, mutect2, varscan2
- TGM5 | c.217A>T p.T73S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55010163; called by muse, mutect2, varscan2
- TLL1 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 93/136 reads (68%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as COSV50282589, COSV50336273, COSV99287092; called by muse, mutect2, varscan2
- TPO | c.163T>C p.Y55H | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV61102446; called by muse, mutect2, varscan2
- TTN | c.13454A>C p.K4485T (on ENST00000591111; = p.K3558T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/107 reads (57%) | PolyPhen benign (0.15); catalogued as COSV60081878; called by muse, mutect2, varscan2
- TTN | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 17/71 reads (24%) | PolyPhen benign (0.02); catalogued as rs754127089, COSV59954418; called by muse, mutect2, varscan2
- USP49 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs1031840505, COSV51897211; called by muse, mutect2, varscan2
- VPS54 | c.97G>C p.V33L | Missense Mutation (SNP) | VAF 60/196 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.07); catalogued as rs771288456, COSV55440993; called by muse, mutect2, varscan2
- WDR93 | c.1883C>T p.P628L | Missense Mutation (SNP) | VAF 69/445 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV51532428; called by muse, mutect2, varscan2
- YIF1A | c.353G>T p.W118L | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1449294314, COSV100268441; called by muse, mutect2, varscan2
- ZBED9 | c.3092C>G p.S1031C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.423); catalogued as COSV71729383; called by muse, mutect2, varscan2
- CTCF | c.864del p.H288Qfs*22 | Frame Shift Del (DEL) | VAF 25/107 reads (23%) | called by mutect2, pindel, varscan2
- FCGBP | c.3237T>G p.H1079Q | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- GRM4 | c.920_922del p.F307del | In Frame Del (DEL) | VAF 6/46 reads (13%) | called by pindel, varscan2
- IGHG1 | c.416C>T p.T139I | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- ABCA12 | c.7536C>T p.Y2512= (on ENST00000272895 / NM_173076.3; = p.Y2194= on NM_015657.3) | Silent (SNP) | VAF 36/72 reads (50%) | catalogued as rs1200082923, CM1413676, COSV55958425, COSV55960192; called by muse, mutect2, varscan2
- ADCY5 | c.828C>T p.A276= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs374267158, COSV71901374; called by muse, mutect2, varscan2
- AHNAK2 | c.8688G>C p.L2896= | Silent (SNP) | VAF 41/245 reads (17%) | catalogued as rs755980026, COSV60916052; called by muse, mutect2, varscan2
- BGN | c.1023C>T p.P341= | Silent (SNP) | VAF 37/77 reads (48%) | catalogued as rs200711767, COSV59036951; called by muse, mutect2, varscan2
- BMP7 | c.1164G>A p.P388= | Silent (SNP) | VAF 20/126 reads (16%) | catalogued as rs751546714, COSV67780852; called by muse, mutect2, varscan2
- CDON | c.468C>A p.I156= | Silent (SNP) | VAF 29/241 reads (12%) | catalogued as rs764436173, COSV54998155; called by muse, mutect2, varscan2
- CHRNA7 | c.1143C>T p.N381= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs542404300, COSV60967848; called by muse, mutect2, varscan2
- CRB1 | c.2115C>T p.P705= | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as COSV66330605; called by muse, mutect2
- CTSO | c.331A>C p.R111= | Silent (SNP) | VAF 78/152 reads (51%) | catalogued as COSV70809159; called by muse, mutect2, varscan2
- DDX60L | c.1284G>A p.S428= | Silent (SNP) | VAF 9/109 reads (8%) | catalogued as rs1222098251, COSV52713909; called by muse, mutect2
- DSG3 | c.276C>A p.I92= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV57126509, COSV99934744; called by muse, mutect2, varscan2
- DUOX1 | c.933G>T p.R311= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as COSV100367998, COSV58483044; called by muse, mutect2, varscan2
- ENGASE | c.2022G>A p.P674= | Silent (SNP) | VAF 25/129 reads (19%) | catalogued as rs770056760, COSV100285750, COSV56135627; called by muse, mutect2, varscan2
- EVC2 | c.2439C>T p.D813= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs370538823; called by muse, mutect2, varscan2
- GPX6 | c.516G>A p.E172= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV62657631; called by muse, mutect2, varscan2
- HMX2 | c.642G>T p.A214= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs959024879, COSV60592812; called by muse, mutect2, varscan2
- INPP4A | c.2916C>T p.Y972= (on ENST00000074304 / NM_001134224.1; = p.Y933= on NM_004027.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as rs761409520, COSV50793756; called by muse, mutect2, varscan2
- ISX | c.666T>G p.T222= | Silent (SNP) | VAF 42/160 reads (26%) | catalogued as COSV100434109, COSV58086618; called by muse, mutect2, varscan2
- MAGI2 | c.1287A>T p.L429= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV62653984, COSV62661766; called by muse, mutect2, varscan2
- MS4A14 | c.588T>C p.N196= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV55733477; called by muse, mutect2
- MUC16 | c.28917C>T p.D9639= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV67468304; called by muse, mutect2, varscan2
- MYH13 | c.2406G>C p.R802= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV52829769; called by muse, mutect2, varscan2
- NTM | c.810A>G p.K270= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs774776729, COSV66180466; called by muse, mutect2, varscan2
- OR5H1 | c.94T>C p.L32= | Silent (SNP) | VAF 66/251 reads (26%) | catalogued as COSV100641609, COSV63402638; called by muse, mutect2, varscan2
- PACSIN1 | c.1131C>T p.G377= | Silent (SNP) | VAF 90/212 reads (42%) | catalogued as COSV55060224; called by muse, mutect2, varscan2
- PCDHB13 | c.1083G>A p.A361= | Silent (SNP) | VAF 43/234 reads (18%) | catalogued as rs1554287820, COSV53396473; called by muse, mutect2, varscan2
- PELI3 | c.615C>T p.A205= | Silent (SNP) | VAF 8/121 reads (7%) | catalogued as rs1006300238, COSV100291871, COSV57856906; called by muse, mutect2
- PJA1 | c.744A>T p.S248= | Silent (SNP) | VAF 21/36 reads (58%) | catalogued as COSV100824728; called by muse, mutect2, varscan2
- PXDNL | c.2682C>T p.I894= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV62481016; called by muse, mutect2, varscan2
- RAET1E | c.420C>T p.F140= | Silent (SNP) | VAF 161/230 reads (70%) | catalogued as COSV61722311; called by muse, mutect2, varscan2
- RBMXL2 | c.723C>T p.R241= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV60980243; called by muse, mutect2
- RPL8 | c.555G>A p.A185= | Silent (SNP) | VAF 12/170 reads (7%) | catalogued as rs188677090, COSV52799271, COSV52799812; called by muse, mutect2
- SCUBE1 | c.1998C>T p.C666= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV62612655; called by muse, mutect2, varscan2
- SEPTIN3 | c.366C>T p.T122= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as rs77263193; called by muse, mutect2, varscan2
- SGCZ | c.588G>A p.P196= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs775208052, COSV66016854; called by muse, mutect2, varscan2
- SLITRK5 | c.2232C>T p.P744= | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as rs966990794, COSV61523056; called by muse, mutect2, varscan2
- TEX14 | c.3495A>G p.S1165= (on ENST00000240361 / NM_001201457.2; = p.S1119= on NM_031272.5) | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs1274726252, COSV53617497; called by muse, mutect2, varscan2
- TRAP1 | c.1527G>A p.E509= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as rs1019782498, COSV55916394; called by muse, mutect2
- ZNF114 | c.564G>A p.P188= | Silent (SNP) | VAF 40/75 reads (53%) | catalogued as rs151202823; called by muse, mutect2, varscan2
- ZNF662 | c.876G>A p.T292= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs369433622; called by muse, mutect2, varscan2
- CHD6 | c.-1G>C | 5'UTR (SNP) | VAF 15/33 reads (45%) | catalogued as COSV100498305; called by muse, mutect2, varscan2
- NRXN1 | c.3365-109728C>T | Intron (SNP) | VAF 9/120 reads (8%) | catalogued as COSV58454765, COSV58483796; called by muse, mutect2
- STON1 | chr2:48529584 G>C | 5'Flank (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
